Somatic mutation profile of tumor specimen HCM-CSHL-0246-C19-01B (aliquot HCM-CSHL-0246-C19-01B-01D-A78L-36) from HCMI case HCM-CSHL-0246-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 55.9 years (20,434 days).
Specimen HCM-CSHL-0246-C19-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 753a5840-98df-4cac-a353-be0fd319012a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0246-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0246-C19-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c85379d9-5348-4405-a994-022a09a88e3a

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 13, Nonsense Mutation 3, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- GRIN2B | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 50/536 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs1057519004, COSV74206831; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 16/257 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2
- BNC2 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.829); catalogued as rs1210859066; called by muse, mutect2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2, varscan2
- CKMT1B | c.1143G>C p.E381D | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV55852209; called by muse, mutect2
- FBN1 | c.4762C>A p.L1588I | Missense Mutation (SNP) | VAF 17/549 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104413959, COSV57322943; called by muse, mutect2
- PAXIP1 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.439); catalogued as rs1444898194; called by muse, mutect2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, mutect2
- PGR | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.742); catalogued as rs749564230, COSV99677589; called by muse, mutect2
- PRDM9 | c.2512G>T p.G838W | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212449977, COSV57006802; called by muse, mutect2
- PTPRM | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs367853227, COSV59857296; called by muse, mutect2, varscan2
- RECQL | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as rs376839517, CM155199, COSV59085001; called by muse, mutect2
- SLC16A2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs1375705723; called by muse, mutect2, varscan2
- TENM1 | c.4283C>T p.A1428V | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1473646016, COSV64439209; called by muse, mutect2
- ZNF628 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99219992; called by muse, mutect2
- ALK | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- FGFR1 | c.1190A>G p.Y397C (on ENST00000447712 / NM_023110.3; = p.Y395C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/412 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- HIVEP3 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2
- IGSF21 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2
- KCNH3 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- SKIV2L | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMAD2 | c.1311G>T p.W437C | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STK39 | c.960A>T p.K320N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- UNC50 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 23/313 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.142); called by muse, mutect2
- VPS13D | c.6484G>C p.D2162H | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- COL22A1 | c.4491C>A p.G1497= | Silent (SNP) | VAF 9/143 reads (6%) | called by muse, mutect2
- FLG | c.4365C>T p.H1455= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as rs142950612; called by muse, mutect2
- GLI3 | c.3066G>A p.P1022= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1206623585, COSV67885002; called by muse, mutect2
- LYAR | c.519A>G p.K173= | Silent (SNP) | VAF 24/339 reads (7%) | called by muse, mutect2
- MAGEB6B | c.945G>A p.G315= | Silent (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- MSH3 | c.2784A>C p.T928= | Silent (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
- MTERF3 | c.993C>T p.T331= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as rs758644998, COSV54635141; called by muse, mutect2, varscan2
- OR11G2 | c.882G>T p.L294= | Silent (SNP) | VAF 9/203 reads (4%) | called by muse, mutect2
- PCDHA2 | c.1335G>T p.V445= | Silent (SNP) | VAF 8/210 reads (4%) | called by muse, mutect2
- PCDHGA8 | c.1935C>T p.A645= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- SERPINA6 | c.78C>T p.N26= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as rs758471605; called by muse, mutect2, varscan2
- THBS2 | c.3243G>A p.A1081= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1166734303; called by muse, mutect2
- ZNF550 | c.420G>C p.V140= | Silent (SNP) | VAF 15/241 reads (6%) | called by muse, mutect2
- AC244517.10 | c.36-10273C>T | Intron (SNP) | VAF 10/184 reads (5%) | catalogued as rs1554290441; called by muse, mutect2
- RPL37AP1 | chr20:44462219 C>T | 3'Flank (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
